CCDI case PBBKBT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/333153d8-691a-4705-818d-86b212bde103

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,759 days).

Biospecimens (3 samples)
- Sample 0DBN9M: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBNBL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBNCT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
